CPTAC case C3L-01046 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5838a973-c162-47cd-a93d-e28fd92f1ca5

Demographics
Sex at birth: male; Race: white; Year of birth: 1966; Vital status: Dead; Days to death: 349 days; Year of death: 2018; Cause of death: Cancer Related; Country of birth: Russia.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 50.9 years (18,595 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 349 days; Days to last follow up: 195 days.
   Pathology details: Greatest tumor dimension: 5 cm.

Follow-up (1 entry)
- Days to follow up: 195 days; Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 195 days; Karnofsky performance status: 0.

Other clinical attributes
- Weight: 110 kg; Height: 185 cm; BMI: 32.14.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 26.3; Cigarettes per day: 35; Tobacco smoking onset year: 1981; Tobacco smoking quit year: 1996; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 15; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01046-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Temporal Cortex; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 370 mg; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01046-21: Section location: left temporal lobe; Percent tumor nuclei: 90; Percent necrosis: 2.
- Sample C3L-01046-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Temporal Cortex; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 380 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01046-24: Section location: left temporal lobe; Percent tumor nuclei: 80; Percent necrosis: 10.
- Sample C3L-01046-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
- Sample C3L-01046-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
